Somatic mutation profile of tumor specimen TCGA-BR-4361-01A (aliquot TCGA-BR-4361-01A-01D-1158-08) from TCGA case TCGA-BR-4361, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 66.4 years (24,260 days).
Specimen TCGA-BR-4361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ebc9839-5483-44f8-92ac-991e0aa18c9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4361-11A (Solid Tissue Normal), aliquot TCGA-BR-4361-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9680921d-924c-49e0-9418-aa9ba6687c4b

The open-access MAF lists 2,864 somatic variants for this specimen: 2,131 protein-altering or splice-affecting, 659 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,555, Silent 659, Frame Shift Del 352, Frame Shift Ins 77, Splice Site 52, Nonsense Mutation 51, Intron 28, Splice Region 27, RNA 19, In Frame Del 14, 3'Flank 10, 5'UTR 7.

Variants (750 of 2,864; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 53/174 reads (30%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 16/51 reads (31%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- BCKDHB | c.714dup p.E239* | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | catalogued as rs1167005638; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CRYGD | c.475del p.A159Pfs*9 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as rs764945940; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 23/92 reads (25%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DNAAF3 | c.997dup p.D333Gfs*64 (on ENST00000524407 / NM_001256715.2; = p.D380Gfs*64 on NM_178837.4) | Frame Shift Ins (INS) | VAF 44/156 reads (28%) | catalogued as rs756430359; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- GABRG2 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520498, COSV62719464; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- GALK1 | c.410del p.G137Vfs*27 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs767329054, CD993840; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KMT2B | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as rs1057519279, COSV52891249; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 47/158 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MFRP | chr11:119345563 del G | 5'Flank (DEL) | VAF 20/79 reads (25%) | catalogued as rs587776596, CD052468, COSV64129114; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 35/114 reads (31%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- MYO7A | c.397del p.H133Tfs*13 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NOTCH3 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1057519101, CM971067, COSV54628402; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5854C>T p.R1952W | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886041219, CM052316, COSV61771898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 26/109 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 43/75 reads (57%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SLC25A13 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs121908532, CM081808, COSV55709470; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 18/68 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ZHX3 | c.747C>A p.N249K | Missense Mutation (SNP) | VAF 35/111 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs201454849, CM121425, COSV58380689; called by muse, mutect2, varscan2
- AAMDC | c.95del p.G32Vfs*23 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as rs753394128; called by mutect2, pindel, varscan2
- AAR2 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as COSV57924295; called by muse, mutect2, varscan2
- AASDH | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.062); catalogued as rs79451123, COSV52707984; called by muse, mutect2, varscan2
- ABCA5 | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67017591; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA7 | c.4131A>C p.E1377D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV54032369; called by muse, mutect2, varscan2
- ABCB7 | c.400C>T p.P134S (on ENST00000373394 / NM_001271696.3; = p.P135S on NM_004299.6) | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as COSV53721075; called by muse, mutect2, varscan2
- ABCC11 | c.947T>G p.L316R | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV62324147; called by muse, varscan2
- ABCC4 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as rs1400854469, COSV65312418; called by muse, mutect2, varscan2
- ABHD6 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.276); catalogued as COSV55909185; called by muse, mutect2, varscan2
- ABI2 | c.1519T>C p.S507P (on ENST00000295851 / NM_001375719.1; = p.S469P on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as rs761629843, COSV53693787; called by muse, mutect2, varscan2
- ABLIM1 | c.1882C>T p.R628W | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1473633676, COSV53309447; called by muse, mutect2, varscan2
- ABTB2 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750330268, COSV54384663; called by muse, mutect2, varscan2
- AC004922.1 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.255); catalogued as COSV53557749; called by muse, mutect2, varscan2
- AC011462.1 | c.145T>C p.F49L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60531934; called by muse, mutect2, varscan2
- ACACB | c.769del p.D257Ifs*17 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | catalogued as rs768607691; called by mutect2, pindel, varscan2
- ACACB | c.4468C>T p.R1490C | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756806908, COSV58138346; called by muse, mutect2, varscan2
- ACACB | c.5623C>A p.L1875M | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV58138364; called by muse, varscan2
- ACADSB | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.384); catalogued as COSV62550997; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | catalogued as rs757016425; called by mutect2, varscan2
- ACLY | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV61251360; called by muse, mutect2
- ACO1 | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59381252; called by muse, mutect2
- ACOT7 | c.1043T>C p.V348A (on ENST00000377855 / NM_181864.3; = p.V338A on NM_007274.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV64114172; called by muse, mutect2, varscan2
- ACP1 | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.303); catalogued as COSV99681448; called by muse, mutect2
- ACSM2A | c.1340G>C p.R447P (on ENST00000219054; = p.R368P on NM_001308169.2) | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54586379; called by muse, mutect2, varscan2
- ACSM2B | c.1340G>C p.R447P | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61658598; called by muse, mutect2, varscan2
- ACSM3 | c.1645dup p.T549Nfs*29 | Frame Shift Ins (INS) | VAF 24/90 reads (27%) | catalogued as rs757021642; called by mutect2, varscan2
- ACTC1 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as COSV51757535, COSV51759864; called by muse, mutect2, varscan2
- ACTR2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV53199572, COSV53201772; called by muse, mutect2, varscan2
- ACTR5 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV54761268; called by muse, mutect2, varscan2
- ACTR8 | c.1643A>G p.Q548R | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.736); catalogued as COSV51637311; called by muse, mutect2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 46/132 reads (35%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVRL1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.712); catalogued as CM040658, COSV66360335; called by muse, mutect2, varscan2
- ACVRL1 | c.1291A>G p.N431D | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV66360459; called by muse, mutect2, varscan2
- ACYP2 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV57816730; called by muse, mutect2
- ADA2 | c.1444T>C p.Y482H (on ENST00000262607; = p.Y241H on NM_177405.3) | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768839234, COSV52832107; called by muse, mutect2
- ADAM17 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV60399835; called by muse, mutect2
- ADAM20 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56455459; called by muse, mutect2
- ADAM21 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV50797894; called by muse, mutect2, varscan2
- ADAM22 | c.1672T>C p.W558R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55981240; called by muse, mutect2, varscan2
- ADAM7 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs1052802267, COSV51542170; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS10 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0.037); catalogued as rs373876511, COSV54359603, COSV99547505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.2633A>G p.H878R | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV61267485; called by muse, mutect2
- ADAMTS16 | c.2363T>C p.V788A | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV56995323; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 50/142 reads (35%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS5 | c.1528G>A p.G510S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.633); catalogued as rs368628024; called by muse, mutect2, varscan2
- ADCY10 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.478); catalogued as rs774828588, COSV63240542; called by muse, mutect2
- ADCY8 | c.2624C>T p.T875I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs775013834, COSV53913986, COSV99655264; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58441785; called by muse, mutect2, varscan2
- ADGRA3 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.227); catalogued as COSV51560348; called by muse, mutect2, varscan2
- ADGRL1 | c.1621G>A p.A541T (on ENST00000340736 / NM_001008701.3; = p.A536T on NM_014921.5) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.241); catalogued as rs749134610, COSV61565346; called by muse, mutect2, varscan2
- ADGRV1 | c.3512A>G p.E1171G | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV67988801; called by muse, mutect2, varscan2
- ADGRV1 | c.8125A>G p.T2709A | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV67988808; called by muse, mutect2, varscan2
- ADGRV1 | c.10611T>A p.N3537K | Missense Mutation (SNP) | VAF 23/542 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV67988812; called by muse, mutect2
- ADGRV1 | c.10790A>G p.E3597G | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV67988813; called by muse, varscan2
- ADH5 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV56448466; called by muse, mutect2, varscan2
- ADNP2 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV51540175; called by muse, mutect2
- ADRA1A | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1281091213, COSV52367564; called by muse, mutect2, varscan2
- ADRA2A | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54528618; called by muse, mutect2, varscan2
- ADRA2C | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57467577; called by muse, mutect2, varscan2
- ADRA2C | c.1261T>C p.F421L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV57467587; called by muse, mutect2, varscan2
- ADRB1 | c.320T>C p.M107T | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV65168078; called by muse, mutect2, varscan2
- AGA | c.807-2A>G p.X269_splice | Splice Site (SNP) | VAF 48/129 reads (37%) | catalogued as COSV52806825; called by muse, mutect2, varscan2
- AGBL2 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs778439327, COSV54093353; called by muse, mutect2, varscan2
- AGBL5 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs545834161, COSV64080011; called by muse, mutect2, varscan2
- AGFG2 | c.1157A>C p.N386T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV53545860; called by muse, mutect2, varscan2
- AGO1 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756692838, COSV64595676; called by muse, mutect2, varscan2
- AGO1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64595681; called by muse, mutect2, varscan2
- AGPS | c.1855+2T>C p.X619_splice | Splice Site (SNP) | VAF 34/99 reads (34%) | catalogued as COSV99930981; called by muse, mutect2, varscan2
- AHCTF1 | c.6446A>G p.N2149S (on ENST00000366508; = p.N2123S on NM_015446.5) | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs772542522, COSV58251930; called by muse, mutect2, varscan2
- AHNAK | c.16619A>G p.D5540G | Missense Mutation (SNP) | VAF 137/385 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs1360198360, COSV57218392; called by muse, mutect2, varscan2
- AHNAK2 | c.11869G>A p.A3957T | Missense Mutation (SNP) | VAF 35/511 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV60920091; called by muse, mutect2
- AHNAK2 | c.10751A>G p.D3584G | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60920095; called by muse, mutect2, varscan2
- AHNAK2 | c.8423C>T p.A2808V | Missense Mutation (SNP) | VAF 50/537 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV60910944; called by muse, mutect2
- AHSA1 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.047); catalogued as COSV53632443; called by muse, mutect2
- AKAP17A | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs759121022, COSV58309239; called by muse, mutect2, varscan2
- AKAP4 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs782646030, COSV62074815; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.11540A>G p.Y3847C (on ENST00000359028; = p.Y3823C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.278); catalogued as COSV50152325; called by muse, mutect2, varscan2
- AKR1C4 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54123959; called by muse, mutect2
- AKR7A2 | c.918+2T>C p.X306_splice | Splice Site (SNP) | VAF 23/109 reads (21%) | catalogued as COSV52516393; called by muse, mutect2, varscan2
- AL133500.1 | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.02); catalogued as COSV55744681, COSV99860499; called by muse, mutect2, varscan2
- ALAD | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV52959543; called by muse, mutect2
- ALDH1L2 | c.2756T>C p.V919A | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51557229; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALDH3A2 | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 67/211 reads (32%) | catalogued as COSV51567552; called by muse, mutect2, varscan2
- ALOXE3 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59076423; called by muse, mutect2, varscan2
- ALPK1 | c.3064T>A p.S1022T | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV51587207; called by muse, mutect2
- ALS2 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as rs777452142, COSV51888836; called by muse, mutect2, varscan2
- AMBP | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54324137; called by muse, mutect2, varscan2
- AMER2 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.44); catalogued as rs553783283, COSV63437784; called by muse, mutect2, varscan2
- AMFR | c.866T>C p.M289T | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV51922530; called by muse, mutect2, varscan2
- AMPD1 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV62416927; called by muse, varscan2
- AMPD2 | c.1814A>G p.Y605C | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99857319; called by mutect2, varscan2
- AMPH | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.116); catalogued as rs748822925, COSV57747270; called by muse, mutect2, varscan2
- ANAPC7 | c.334A>G p.K112E | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV71443878; called by muse, varscan2
- ANK1 | c.4501G>A p.D1501N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs775820344, COSV55885808; called by muse, mutect2, varscan2
- ANK2 | c.7697A>G p.H2566R | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV52170370; called by muse, mutect2, varscan2
- ANK2 | c.8020A>T p.K2674* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | catalogued as COSV52170383; called by muse, mutect2, varscan2
- ANK3 | c.4743A>G p.I1581M | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55065585; called by muse, mutect2, varscan2
- ANKFY1 | c.2614C>T p.R872W (on ENST00000341657 / NM_001330063.2; = p.R873W on NM_016376.5) | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372638146; called by muse, mutect2, varscan2
- ANKRD12 | c.2804del p.N935Ifs*24 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs868780344; called by mutect2, varscan2
- ANKRD17 | c.7150G>A p.A2384T | Missense Mutation (SNP) | VAF 134/431 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV58223128; called by muse, mutect2, varscan2
- ANKRD35 | c.1946G>A p.S649N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1553739116, COSV62910832; called by muse, mutect2, varscan2
- ANKS1B | c.3287C>T p.T1096I (on ENST00000547776 / NM_152788.4; = p.T262I on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59121363; called by muse, mutect2
- ANO5 | c.1898+2T>C p.X633_splice | Splice Site (SNP) | VAF 14/91 reads (15%) | catalogued as COSV61087038; called by muse, mutect2, varscan2
- ANO5 | c.2093T>C p.L698P | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61087048; called by muse, mutect2, varscan2
- ANO6 | c.1830A>G p.I610M | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57663421; called by muse, mutect2, varscan2
- ANO6 | c.2267A>G p.Y756C | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV57663436; called by muse, mutect2, varscan2
- ANP32B | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV59587076; called by muse, mutect2, varscan2
- AOAH | c.254T>C p.L85S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.093); catalogued as COSV51744478; called by muse, mutect2, varscan2
- AP1S2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV61306836; called by muse, mutect2, varscan2
- AP4E1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV55918043; called by muse, mutect2, varscan2
- AP5B1 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs368800811; called by muse, mutect2, varscan2
- APC | c.5362C>T p.R1788C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as rs773125634, COSV57355907; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEX2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); catalogued as rs763356429, COSV66624147; called by muse, mutect2, varscan2
- APOBEC3D | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 34/124 reads (27%) | catalogued as rs1182018455, COSV53327174; called by muse, mutect2, varscan2
- APOF | c.705del p.P236Lfs*4 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as COSV58477085; called by mutect2, pindel, varscan2
- APPL1 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 103/385 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55701717; called by muse, mutect2, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- AQR | c.895del p.S299Pfs*23 | Frame Shift Del (DEL) | VAF 43/127 reads (34%) | catalogued as COSV50030271; called by mutect2, pindel, varscan2
- ARAP3 | c.3847C>T p.R1283C | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs963954078, COSV53351021; called by muse, varscan2
- ARFGAP2 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV54066538; called by muse, mutect2
- ARFRP1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs367735078, COSV53928784; called by muse, mutect2, varscan2
- ARG1 | c.497C>T p.T166I | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV51581299; called by muse, mutect2, varscan2
- ARHGAP15 | c.131T>C p.M44T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV54504664; called by muse, mutect2, varscan2
- ARHGAP21 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV57607599; called by muse, mutect2
- ARHGAP28 | c.1169G>A p.R390Q (on ENST00000383472 / NM_001366230.1; = p.R231Q on NM_001010000.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs761051990, COSV51640686; called by muse, varscan2
- ARHGAP35 | c.3433C>T p.R1145* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV68329138; called by muse, mutect2, varscan2
- ARHGAP45 | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV57433476; called by muse, mutect2, varscan2
- ARHGEF11 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1557838551, COSV59355702; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 40/145 reads (28%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARHGEF40 | c.2767C>T p.R923W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs903600980, COSV53881662; called by muse, mutect2, varscan2
- ARHGEF6 | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51692787; called by muse, mutect2, varscan2
- ARL10 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs769324573, COSV59991051; called by muse, mutect2, varscan2
- ARPP21 | c.2224T>C p.Y742H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51801331; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs747570359; called by mutect2, varscan2
- ASS1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs764331417, COSV61689809; called by muse, varscan2
- ASTE1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs750336679, COSV53909167; called by muse, mutect2, varscan2
- ASTE1 | c.848del p.K283Rfs*22 | Frame Shift Del (DEL) | VAF 39/141 reads (28%) | catalogued as rs34815684; called by mutect2, pindel, varscan2
- ASTL | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV60904671; called by muse, mutect2
- ATF5 | c.806T>C p.I269T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV61312614; called by muse, mutect2, varscan2
- ATG2A | c.4671+1G>A p.X1557_splice | Splice Site (SNP) | VAF 24/70 reads (34%) | catalogued as COSV65967361; called by muse, mutect2, varscan2
- ATG2B | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV63424074; called by muse, mutect2
- ATG9A | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54697316; called by muse, mutect2, varscan2
- ATM | c.4977A>G p.I1659M | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53753309; called by muse, mutect2, varscan2
- ATMIN | c.2282A>G p.N761S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV55146622; called by muse, mutect2
- ATP10D | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs757458517, COSV56709304; called by muse, mutect2, varscan2
- ATP1A1 | c.1640del p.G547Afs*7 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs760784617; called by mutect2, pindel
- ATP2C1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs756074470, COSV60758511; called by muse, mutect2
- ATP6AP2 | c.301-1G>T p.X101_splice | Splice Site (SNP) | VAF 11/127 reads (9%) | catalogued as COSV65797969; called by muse, mutect2
- ATP6V0E2 | c.235C>A p.L79M (on ENST00000425642; = p.L128M on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.195); catalogued as COSV101374566; called by muse, mutect2, varscan2
- ATP8B1 | c.2821C>T p.R941* | Nonsense Mutation (SNP) | VAF 35/110 reads (32%) | catalogued as rs374340059, CM1510508; called by muse, mutect2, varscan2
- ATP8B1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV52177384; called by muse, mutect2, varscan2
- ATP8B2 | c.2689T>C p.S897P (on ENST00000672630; = p.S864P on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 265/809 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59246829; called by muse, mutect2, varscan2
- ATRNL1 | c.3752T>C p.V1251A | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58095764; called by muse, mutect2, varscan2
- ATRX | c.5203A>G p.M1735V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV64878952; called by muse, mutect2
- ATXN2 | c.3308C>T p.A1103V (on ENST00000550104; = p.A943V on NM_002973.4) | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs1287322286, COSV66483349, COSV66485298; called by muse, mutect2, varscan2
- ATXN2 | c.1880C>A p.A627D (on ENST00000550104; = p.A467D on NM_002973.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs1471573038, COSV66484231; called by muse, mutect2, varscan2
- AURKB | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV100298738, COSV60244994; called by muse, mutect2, varscan2
- AZU1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52141530; called by muse, mutect2, varscan2
- B3GALNT2 | c.1393A>G p.T465A | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as COSV64004202; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972del p.G991Vfs*71 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs35951843; called by mutect2, pindel, varscan2
- B4GALT5 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1457689672, COSV65494244; called by muse, mutect2, varscan2
- B9D2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs149500212; called by muse, mutect2, varscan2
- BACH2 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.853); catalogued as COSV57598281; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs185758992; called by muse, mutect2, varscan2
- BAIAP3 | c.1576A>G p.T526A | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV60981369; called by muse, mutect2, varscan2
- BARD1 | c.1439T>C p.L480S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs149839922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCKDK | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54892706; called by muse, mutect2, varscan2
- BCL11A | c.1138T>C p.C380R (on ENST00000335712 / NM_001365609.1; = p.C414R on NM_018014.4) | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59633049; called by muse, mutect2, varscan2
- BCL2 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.23); catalogued as COSV61373542, COSV61384445; called by muse, mutect2
- BCL2L11 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV58030907; called by muse, mutect2, varscan2
- BCL2L2 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV51636190; called by muse, mutect2, varscan2
- BCL9L | c.3127A>G p.T1043A | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52686213; called by muse, mutect2
- BCORL1 | c.3902T>C p.M1301T | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV54399547; called by muse, mutect2, varscan2
- BEND2 | c.158A>C p.N53T | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV66216277; called by muse, mutect2, varscan2
- BICD1 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs986503549, COSV55682069; called by muse, mutect2, varscan2
- BICRAL | c.1193A>G p.Q398R | Missense Mutation (SNP) | VAF 42/761 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV58406757; called by muse, mutect2
- BIVM-ERCC5 | c.897A>C p.E299D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57280667; called by muse, mutect2, varscan2
- BLVRA | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1289358391, COSV55515023; called by muse, mutect2
- BMPR1A | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.373); catalogued as COSV64406821; called by muse, mutect2, varscan2
- BNC1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.688); catalogued as rs146985300; called by muse, mutect2, varscan2
- BOD1L1 | c.6302C>T p.T2101I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV50021905; called by muse, mutect2, varscan2
- BPTF | c.7949A>G p.E2650G | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58840285; called by muse, mutect2
- BRCA2 | c.4855A>G p.N1619D | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV66456645; called by muse, mutect2, varscan2
- BRCA2 | c.7051G>A p.A2351T | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as rs80358930, COSV66456444; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD8 | c.2037G>C p.Q679H (on ENST00000254900 / NM_139199.2; = p.Q752H on NM_006696.4) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV50155077; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BSN | c.3060G>T p.K1020N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56521558; called by muse, mutect2, varscan2
- BTBD7 | c.902A>G p.E301G | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54137328; called by muse, mutect2, varscan2
- BTN2A1 | c.1144G>T p.A382S | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV57003669, COSV57004362; called by muse, mutect2, varscan2
- BUB1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 104/407 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.973); catalogued as rs375036331; ClinVar: likely benign; called by muse, mutect2, varscan2
- C1QL1 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53647614; called by muse, mutect2, varscan2
- C20orf27 | c.329C>T p.A110V (on ENST00000379772 / NM_001258429.2; = p.A135V on NM_001039140.3) | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs769544672, COSV53924494; called by muse, mutect2, varscan2
- C20orf85 | c.383A>C p.E128A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV64519531; called by muse, mutect2, varscan2
- C21orf58 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.017); catalogued as COSV52450380; called by muse, mutect2
- C2CD2 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV61599892; called by muse, mutect2, varscan2
- C3 | c.2027C>T p.T676M | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139945572; called by muse, mutect2, varscan2
- C3AR1 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV50820108; called by muse, mutect2, varscan2
- C9 | c.527T>C p.F176S | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV54678192; called by muse, mutect2, varscan2
- C9orf131 | c.3195A>C p.K1065N | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV56612178; called by muse, mutect2
- C9orf72 | c.671T>G p.I224S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV66154857; called by muse, mutect2, varscan2
- CACNA1B | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769225657, COSV99494980; called by muse, mutect2
- CACNA1B | c.4054C>T p.L1352F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV53133565; called by muse, mutect2, varscan2
- CACNA1C | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs761378545, COSV59737906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.2473+2T>C p.X825_splice (on ENST00000350061 / NM_001128840.3; = p.X845_splice on NM_000720.4) | Splice Site (SNP) | VAF 5/83 reads (6%) | catalogued as COSV55440087; called by muse, mutect2
- CACNA1D | c.6155G>A p.S2052N (on ENST00000350061 / NM_001128840.3; = p.S2072N on NM_000720.4) | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.147); catalogued as COSV55453510; called by muse, mutect2
- CACNA1E | c.988T>C p.Y330H | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62402549; called by muse, mutect2, varscan2
- CACNA1S | c.4946A>G p.Q1649R | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.009); catalogued as COSV62941128; called by muse, mutect2, varscan2
- CACNA1S | c.3526-1G>T p.X1176_splice | Splice Site (SNP) | VAF 16/31 reads (52%) | catalogued as COSV62941132; called by muse, mutect2, varscan2
- CACNA1S | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs779029870, COSV62941137; called by muse, mutect2, varscan2
- CACTIN | c.1637T>C p.L546P | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV50269422; called by muse, mutect2, varscan2
- CADM1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as rs1053413125, COSV59014747; called by muse, mutect2, varscan2
- CALCA | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as rs782681062, COSV59027546; called by muse, mutect2, varscan2
- CAMK1G | c.1165C>A p.L389I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); catalogued as COSV50523232; called by muse, mutect2, varscan2
- CAMK2G | c.401A>G p.H134R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV59483151; called by muse, mutect2, varscan2
- CAMK4 | c.293A>G p.H98R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV56675314; called by muse, mutect2, varscan2
- CAMKK1 | c.1022T>C p.V341A | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV50120096; called by muse, mutect2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 11/94 reads (12%) | catalogued as rs754747174; called by mutect2, varscan2
- CAMSAP3 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.099); catalogued as COSV99349753; called by muse, mutect2, varscan2
- CAPN12 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201015038, COSV61016928; called by muse, mutect2, varscan2
- CAPN15 | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54837275; called by muse, mutect2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 40/82 reads (49%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARMIL3 | c.2558A>G p.H853R | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV57727120; called by muse, mutect2, varscan2
- CASP3 | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57725330; called by muse, mutect2
- CASP4 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs559503139, COSV67744211; called by muse, mutect2, varscan2
- CAV1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs769406995, COSV61952793; called by muse, mutect2, varscan2
- CAVIN1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 70/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63811601; called by muse, mutect2, varscan2
- CBFB | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51999391; called by muse, mutect2, varscan2
- CBR3 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV51741303; called by muse, mutect2
- CCDC117 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745967615, COSV50770859; called by muse, mutect2, varscan2
- CCDC151 | c.1700A>G p.N567S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV62698338; called by muse, mutect2, varscan2
- CCDC171 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs141114992; called by muse, mutect2, varscan2
- CCDC171 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs373672355; called by muse, varscan2
- CCDC171 | c.3590T>C p.V1197A | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as COSV52644700, COSV52645155; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC18 | c.290del p.K97Sfs*24 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs1557593229, COSV100159192; called by mutect2, pindel, varscan2
- CCDC22 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as rs201055378, COSV59905252; called by muse, mutect2, varscan2
- CCDC40 | c.1919T>C p.M640T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV66476132; called by muse, mutect2, varscan2
- CCDC50 | c.625T>A p.S209T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV101165241; called by muse, mutect2, varscan2
- CCDC57 | c.2609A>G p.Q870R | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV60757061; called by muse, mutect2, varscan2
- CCDC6 | c.1105+2T>C p.X369_splice | Splice Site (SNP) | VAF 32/92 reads (35%) | catalogued as COSV54057656; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC74A | c.980T>C p.V327A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99723532; called by muse, mutect2, varscan2
- CCDC88A | c.496A>G p.N166D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV55064639; called by muse, mutect2, varscan2
- CCNB1IP1 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as rs1294577400, COSV62303073; called by muse, mutect2, varscan2
- CCNL1 | c.1102A>G p.R368G | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV55819750; called by muse, mutect2, varscan2
- CCT8 | c.1472A>G p.D491G | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV54504727; called by muse, mutect2, varscan2
- CCT8 | c.562+1G>A p.X188_splice | Splice Site (SNP) | VAF 26/67 reads (39%) | catalogued as COSV54504736; called by muse, mutect2, varscan2
- CCZ1B | c.1010A>T p.D337V | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100367708; called by muse, mutect2, varscan2
- CD276 | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59202900, COSV59204289; called by muse, mutect2, varscan2
- CD36 | c.719A>G p.E240G | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV59214958; called by muse, mutect2, varscan2
- CD6 | c.470-2A>G p.X157_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV57840109; called by muse, mutect2, varscan2
- CD8A | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.574); catalogued as COSV52156850, COSV52158608; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDC14A | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs1482824856, COSV60559906; called by muse, mutect2, varscan2
- CDC42 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV59662642; called by muse, mutect2, varscan2
- CDCA4 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs555120853, COSV60315654; called by muse, mutect2, varscan2
- CDCA5 | c.59del p.P20Hfs*41 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs1268014123; called by mutect2, pindel, varscan2
- CDH2 | c.399+2T>C p.X133_splice | Splice Site (SNP) | VAF 10/266 reads (4%) | catalogued as COSV52285429; called by muse, mutect2
- CDH23 | c.2890C>T p.R964W | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs768031780, COSV99818605; ClinVar: uncertain significance; called by muse, mutect2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 43/174 reads (25%) | catalogued as rs868286996; called by mutect2, pindel, varscan2
- CDK15 | c.910T>C p.S304P (on ENST00000652192 / NM_001366386.2; = p.S253P on NM_139158.2) | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV53635777; called by muse, mutect2
- CDK18 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); catalogued as rs747729060, COSV63728081; called by muse, mutect2, varscan2
- CDKAL1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV51181063; called by muse, varscan2
- CDKL5 | c.2200A>G p.T734A | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.014); catalogued as rs55803460, COSV66111972; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- CDKN1A | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.419); catalogued as COSV55189837; called by mutect2, varscan2
- CDNF | c.466dup p.E156Gfs*11 | Frame Shift Ins (INS) | VAF 64/264 reads (24%) | catalogued as rs1183960049; called by pindel, varscan2
- CDYL | c.460G>A p.V154M (on ENST00000328908 / NM_001368125.1; = p.V100M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs757700421, COSV59360401; called by muse, mutect2, varscan2
- CECR2 | c.826A>G p.S276G (on ENST00000342247 / NM_001290047.2; = p.S113G on NM_001290046.1) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52843999; called by muse, mutect2, varscan2
- CELF4 | c.773T>C p.F258S | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as COSV58457895; called by muse, mutect2
- CELSR1 | c.3559G>A p.V1187I | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.234); catalogued as rs748498695, COSV53093458; called by muse, mutect2, varscan2
- CELSR3 | c.4931G>A p.G1644D | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50896069; called by muse, mutect2, varscan2
- CELSR3 | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); catalogued as COSV50874312, COSV50896306; called by muse, mutect2, varscan2
- CEMIP2 | c.2279A>G p.H760R | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV65488024; called by muse, mutect2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CENPF | c.8239G>T p.D2747Y | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65276204; called by muse, mutect2, varscan2
- CENPJ | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs748815881, COSV67883669; called by muse, mutect2, varscan2
- CEP104 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs372416064; called by muse, mutect2, varscan2
- CEP120 | c.2360T>C p.L787P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV60266505; called by mutect2, varscan2
- CEP126 | c.2745A>T p.E915D | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV54827207; called by muse, mutect2, varscan2
- CEP350 | c.6055C>G p.H2019D | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV62604965; called by muse, mutect2
- CEP57 | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV57689211; called by muse, mutect2, varscan2
- CEP97 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59125595; called by muse, mutect2, varscan2
- CES2 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57696846, COSV57697217; called by muse, mutect2
- CFAP46 | c.7166G>A p.S2389N | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.068); catalogued as COSV99583851; called by muse, mutect2
- CFAP46 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.711); catalogued as rs1029661203, COSV63952274; called by muse, mutect2, varscan2
- CFAP47 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52887357; called by muse, mutect2, varscan2
- CFAP52 | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1443308732, COSV55346296; called by muse, mutect2
- CFAP54 | c.6593T>C p.L2198P | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61573016; called by muse, mutect2, varscan2
- CFAP61 | c.1855C>T p.R619* | Nonsense Mutation (SNP) | VAF 87/265 reads (33%) | catalogued as COSV55618034, COSV55618947; called by muse, mutect2, varscan2
- CFAP69 | c.2657T>C p.V886A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as COSV60186686; called by muse, mutect2
- CGAS | c.1217+1G>T p.X406_splice | Splice Site (SNP) | VAF 16/64 reads (25%) | catalogued as COSV64808441; called by muse, varscan2
- CGN | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1557986482, COSV54971306; called by muse, mutect2, varscan2
- CGN | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1292331764, COSV54970824; called by muse, varscan2
- CHD7 | c.6212A>G p.H2071R | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV71112307; called by muse, mutect2, varscan2
- CHEK2 | c.1757T>C p.L586S (on ENST00000382580 / NM_001005735.2; = p.L543S on NM_007194.4) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60422248; called by muse, varscan2
- CHEK2 | c.1751C>G p.A584G (on ENST00000382580 / NM_001005735.2; = p.A541G on NM_007194.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.194); catalogued as COSV60422270; called by muse, varscan2
- CHM | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV63302701; called by muse, mutect2, varscan2
- CHRNA1 | c.754A>G p.M252V (on ENST00000261007 / NM_001039523.3; = p.M227V on NM_000079.4) | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs111856577, COSV53683438; called by muse, mutect2, varscan2
- CHRNA5 | c.258+2T>C p.X86_splice | Splice Site (SNP) | VAF 37/169 reads (22%) | catalogued as COSV55137778; called by muse, varscan2
- CHRNA9 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 37/397 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.361); catalogued as COSV59574951; called by muse, mutect2, varscan2
- CHRNB4 | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55716774; called by muse, mutect2
- CHST12 | c.173G>T p.R58M | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV51676281; called by muse, mutect2, varscan2
- CHSY1 | c.1153T>C p.Y385H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54254446; called by muse, mutect2, varscan2
- CHTF18 | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs376512999, COSV50101088; called by muse, mutect2, varscan2
- CIITA | c.64T>C p.C22R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.041); catalogued as rs774713571, COSV60859127; called by muse, mutect2, varscan2
- CIPC | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs755991866, COSV62377167; called by muse, mutect2, varscan2
- CLCA1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV52328835; called by muse, mutect2, varscan2
- CLCN3 | c.694T>C p.F232L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV61627690; called by muse, mutect2, varscan2
- CLCN7 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs764870423, COSV51971581; called by muse, mutect2, varscan2
- CLDN12 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55307220; called by muse, mutect2, varscan2
- CLDN18 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs748868334, COSV99480577; called by muse, mutect2, varscan2
- CLDN20 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65697601; called by muse, mutect2, varscan2
- CLDN23 | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67731580; called by muse, mutect2, varscan2
- CLDN6 | c.567dup p.S190Vfs*24 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | catalogued as rs756736939; called by mutect2, varscan2
- CLEC16A | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1194773594, COSV55489303, COSV55490403; called by muse, mutect2, varscan2
- CLGN | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57775265; called by muse, mutect2, varscan2
- CLIC6 | c.1748dup p.N583Kfs*8 (on ENST00000360731 / NM_001317009.2; = p.N565Kfs*8 on NM_053277.3) | Frame Shift Ins (INS) | VAF 22/84 reads (26%) | catalogued as rs753268577; called by mutect2, pindel, varscan2
- CLK3 | c.1837G>A p.E613K (on ENST00000395066 / NM_001130028.1; = p.E465K on NM_003992.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs1391769502, COSV59340824; called by muse, mutect2, varscan2
- CLSTN1 | c.1937T>C p.M646T (on ENST00000377298 / NM_001009566.3; = p.M636T on NM_014944.4) | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63648952; called by muse, mutect2
- CLUH | c.3374G>A p.R1125H (on ENST00000435359; = p.R1164H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as rs1241641121, COSV70929316; called by muse, mutect2, varscan2
- CLUH | c.349C>T p.R117C (on ENST00000435359; = p.R155C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV70928770; called by muse, mutect2
- CLUL1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 110/339 reads (32%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.454); catalogued as rs753466551, COSV100621034, COSV58111541, COSV58111821; called by muse, mutect2, varscan2
- CMSS1 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV70439008; called by muse, mutect2, varscan2
- CMYA5 | c.2510G>T p.G837V | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV71407065; called by muse, mutect2, varscan2
- CNGA3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs770052346, COSV55624718; called by muse, mutect2, varscan2
- CNNM2 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV63996152; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 54/257 reads (21%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNPPD1 | c.1128dup p.W377Lfs*50 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | catalogued as rs764842458; called by mutect2, pindel, varscan2
- CNTLN | c.2456A>T p.Y819F | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.201); catalogued as rs369975567, COSV52084525; called by muse, mutect2, varscan2
- CNTLN | c.4037A>G p.Q1346R | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52084534; called by muse, mutect2, varscan2
- CNTN1 | c.2454A>C p.K818N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV100751778, COSV61641701; called by muse, varscan2
- CNTN1 | c.2591A>G p.Y864C | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); catalogued as COSV61639439; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV62208733; called by muse, varscan2
- CNTNAP2 | c.3934A>G p.M1312V | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1477213560, COSV62208735; called by muse, mutect2
- CNTNAP4 | c.3335A>C p.E1112A | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as COSV56688088; called by muse, mutect2, varscan2
- COBLL1 | c.2245G>A p.V749I (on ENST00000392717; = p.V711I on NM_014900.5) | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181143305, COSV52070625; called by muse, mutect2, varscan2
- COG1 | c.1111A>G p.M371V | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748060400, COSV55430542; called by muse, mutect2, varscan2
- COL11A1 | c.4131del p.G1378Vfs*80 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as COSV62192406; called by mutect2, pindel
- COL11A1 | c.1636C>G p.P546A | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777447423, COSV62183245; called by muse, mutect2, varscan2
- COL14A1 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs767547791, COSV52859176; called by muse, mutect2, varscan2
- COL1A2 | c.3392A>C p.K1131T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as rs994598283, COSV51960708; called by muse, mutect2, varscan2
- COL5A1 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.885); catalogued as rs770793962, COSV65667804; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL5A2 | c.3913G>A p.A1305T | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs372897632; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.8008G>A p.A2670T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs398124135, COSV55112590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A2 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV57442338; called by muse, mutect2
- COQ8B | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.544); catalogued as COSV54687657; called by muse, mutect2, varscan2
- CORO7 | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs145925246; called by muse, mutect2, varscan2
- COX15 | c.302A>T p.D101V | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV50012601; called by muse, mutect2, varscan2
- CPA1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99163212; called by muse, varscan2
- CPA6 | c.1207G>A p.G403R | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52734170; called by muse, mutect2, varscan2
- CPM | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); catalogued as COSV58034173; called by muse, mutect2, varscan2
- CPNE4 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV101456747, COSV70190669; called by muse, mutect2, varscan2
- CPS1 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147443001; called by muse, mutect2, varscan2
- CPSF1 | c.2069A>G p.H690R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV58234239; called by muse, varscan2
- CPSF4 | c.119T>C p.V40A | Missense Mutation (SNP) | VAF 119/529 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as COSV52858161; called by muse, mutect2, varscan2
- CPVL | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200681795, COSV55304642; called by muse, varscan2
- CPXM2 | c.931A>G p.T311A | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs776218004, COSV99580912; called by muse, mutect2
- CRACDL | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67408902; called by muse, mutect2, varscan2
- CRBN | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51641584; called by muse, mutect2, varscan2
- CREB3 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs758225343, COSV59209013; called by muse, mutect2, varscan2
- CREBBP | c.2843A>G p.Q948R | Missense Mutation (SNP) | VAF 88/363 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.953); catalogued as COSV52129356; called by muse, mutect2, varscan2
- CRLF1 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV62260768; called by muse, mutect2, varscan2
- CRNKL1 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 123/400 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs141413150; called by muse, mutect2, varscan2
- CRTAC1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760650627, COSV54004298; called by muse, mutect2, varscan2
- CSF2RA | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 98/301 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62625316; called by muse, mutect2, varscan2
- CSGALNACT1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1194788527, COSV59976710, COSV59978644; called by muse, mutect2, varscan2
- CSMD3 | c.10990G>T p.G3664* (on ENST00000297405 / NM_001363185.1; = p.G3495* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 48/192 reads (25%) | catalogued as COSV52194223; called by muse, varscan2
- CSMD3 | c.10150C>A p.L3384I (on ENST00000297405 / NM_001363185.1; = p.L3215I on NM_052900.3) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.136); catalogued as COSV52167559, COSV52225975; called by muse, mutect2, varscan2
- CSMD3 | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV52226000; called by muse, mutect2, varscan2
- CSNK1E | c.142del p.Q48Sfs*11 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs1569079288; called by mutect2, pindel, varscan2
- CSRP2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1457151294, COSV60702935; called by muse, mutect2, varscan2
- CST11 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 85/309 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.22); catalogued as COSV63140165; called by muse, mutect2, varscan2
- CSTF3 | c.1294A>T p.I432F | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60612436; called by muse, mutect2
- CTBP1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52074899; called by muse, mutect2, varscan2
- CTIF | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as COSV56486557; called by muse, mutect2, varscan2
- CTSC | c.1004A>T p.E335V | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV57058658; called by muse, mutect2, varscan2
- CTSG | c.210A>G p.I70M | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.667); catalogued as rs1434030483, COSV53536034; called by muse, mutect2
- CTSS | c.571T>C p.Y191H | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64566552; called by muse, mutect2, varscan2
- CTTN | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs373870325; called by muse, mutect2, varscan2
- CTTNBP2 | c.3848G>T p.R1283M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50415355; called by muse, mutect2, varscan2
- CTTNBP2 | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV50415434; called by muse, mutect2
- CUX2 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV55637712; called by muse, mutect2, varscan2
- CX3CL1 | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs762102080, COSV50056188; called by muse, mutect2, varscan2
- CXCL16 | c.439T>C p.S147P | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV53411774; called by muse, mutect2, varscan2
- CXCL2 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1418852833, COSV56021809; called by muse, mutect2, varscan2
- CXorf56 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV57438616; called by muse, mutect2
- CYGB | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.24); catalogued as rs200693197; called by muse, mutect2, varscan2
- CYP11A1 | c.863T>C p.L288S | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.914); catalogued as COSV51432920; called by muse, mutect2, varscan2
- CYP1A2 | c.1498A>G p.K500E | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59660106; called by muse, mutect2, varscan2
- CYP3A7 | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.176); catalogued as COSV60482115; called by muse, mutect2
- CYP4F11 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs758162397, COSV56127244; called by muse, mutect2, varscan2
- CYRIA | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as rs1401651461, COSV62865705; called by muse, mutect2, varscan2
- CYTH1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs780397308, COSV63119580, COSV63121697; called by mutect2, varscan2
- CYTH1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV63121710; called by muse, mutect2, varscan2
- DAAM1 | c.922T>A p.F308I | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62837524; called by muse, mutect2, varscan2
- DAAM1 | c.3053G>A p.R1018H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs753779506, COSV62837530; called by muse, mutect2, varscan2
- DAB2 | c.112T>C p.Y38H | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); catalogued as COSV57916036; called by muse, mutect2
- DACT1 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 32/128 reads (25%) | catalogued as COSV60021775; called by muse, mutect2, varscan2
- DAG1 | c.2318T>C p.I773T | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58185300; called by muse, mutect2, varscan2
- DAPK2 | c.986C>G p.T329S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99977015; called by muse, mutect2, varscan2
- DAXX | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV56470781; called by muse, mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DAZAP1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.177); catalogued as COSV51833872; called by muse, mutect2, varscan2
- DBX1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 85/166 reads (51%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.009); catalogued as rs775280771, COSV57054405; called by muse, mutect2, varscan2
- DCAF11 | c.757A>G p.T253A | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV58109681; called by muse, mutect2, varscan2
- DCAF4 | c.844A>T p.I282F | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62319949; called by muse, mutect2, varscan2
- DCAF4L2 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60479895; called by muse, mutect2, varscan2
- DCBLD1 | c.1258T>C p.S420P | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.77); catalogued as COSV51643017; called by muse, mutect2, varscan2
- DCC | c.4015A>G p.T1339A | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.145); catalogued as rs1476824565, COSV71434255, COSV71438899; called by muse, mutect2
- DCHS2 | n.5213A>G | Splice Region (SNP) | VAF 32/83 reads (39%) | catalogued as COSV61774656; called by muse, mutect2, varscan2
- DCLRE1C | c.2053del p.R685Efs*6 (on ENST00000378278 / NM_001350965.2; = p.R570Efs*6 on NM_022487.4) | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs915913541; called by mutect2, pindel, varscan2
- DCT | c.555dup p.V186Cfs*9 | Frame Shift Ins (INS) | VAF 48/176 reads (27%) | catalogued as rs762895555; called by mutect2, varscan2
- DCTN1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs763277715, COSV62620825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDI1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV56373290; called by muse, mutect2
- DDR2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs769041297, COSV63372107; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX20 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63831249, COSV63831769; called by muse, mutect2, varscan2
- DDX39A | c.790T>C p.Y264H | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.063); catalogued as COSV54392043; called by muse, mutect2, varscan2
- DDX3X | c.325C>T p.R109C (on ENST00000399959; = p.R110C on NM_001356.5) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs1444942370, COSV101302352, COSV67863950; called by muse, mutect2, varscan2
- DDX47 | c.370+2T>C p.X124_splice | Splice Site (SNP) | VAF 12/200 reads (6%) | catalogued as COSV61911664; called by muse, mutect2
- DENND4C | c.5833A>G p.S1945G (on ENST00000434457 / NM_001330640.2; = p.S1896G on NM_017925.7) | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.209); catalogued as rs758943460, COSV59548182; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | catalogued as COSV59384233; called by mutect2, varscan2
- DGKB | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV51796003; called by muse, mutect2
- DGKZ | c.1344_1345insC p.K449Qfs*17 (on ENST00000454345 / NM_001105540.2; = p.K261Qfs*17 on NM_003646.4) | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as COSV58984107, COSV58987748; called by mutect2, pindel, varscan2
- DGKZ | c.1606C>T p.R536W (on ENST00000454345 / NM_001105540.2; = p.R348W on NM_003646.4) | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs977532548, COSV58990803; called by muse, mutect2, varscan2
- DHH | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 12/319 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV57202303; called by muse, mutect2
- DHRS9 | c.669dup p.L224Tfs*21 | Frame Shift Ins (INS) | VAF 22/63 reads (35%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX30 | c.1951G>A p.D651N (on ENST00000445061 / NM_138615.3; = p.D612N on NM_014966.3) | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.137); catalogued as rs748383690, COSV53136830; called by muse, mutect2, varscan2
- DHX36 | c.2114T>C p.M705T | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100273825, COSV57674335; called by muse, mutect2, varscan2
- DHX37 | c.872A>G p.E291G | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58136179; called by muse, mutect2, varscan2
- DHX37 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV58136192; called by muse, mutect2, varscan2
- DIABLO | c.96G>T p.K32N (on ENST00000443649 / NM_001278303.1; = p.K105N on NM_019887.6) | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV57336812; called by muse, mutect2, varscan2
- DIAPH2 | c.1935+2T>C p.X645_splice | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as COSV61276900; called by muse, mutect2
- DIAPH3 | c.3055del p.R1019Efs*12 (on ENST00000400324 / NM_001042517.2; = p.R756Efs*12 on NM_030932.3) | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | catalogued as rs753024929; called by mutect2, pindel, varscan2
- DIDO1 | c.5234del p.G1745Afs*119 | Frame Shift Del (DEL) | VAF 47/187 reads (25%) | catalogued as COSV99825386; called by mutect2, pindel, varscan2
- DIMT1 | c.296A>T p.Q99L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV52233968; called by muse, mutect2, varscan2
- DIP2A | c.2162A>G p.Q721R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1292979208, COSV59480527; called by muse, mutect2
- DIP2C | c.1150-1G>T p.X384_splice | Splice Site (SNP) | VAF 15/53 reads (28%) | catalogued as COSV55164946; called by muse, mutect2, varscan2
- DLC1 | c.1849del p.R617Gfs*37 (on ENST00000276297 / NM_001348081.2; = p.R180Gfs*37 on NM_006094.5) | Frame Shift Del (DEL) | VAF 25/180 reads (14%) | catalogued as COSV52307798; called by pindel, varscan2
- DLGAP2 | c.1040A>G p.N347S | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs376158978; called by muse, varscan2
- DLGAP2 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs767514905, COSV70100262; called by muse, varscan2
- DLGAP4 | c.2150A>G p.D717G (on ENST00000339266 / NM_001365621.1; = p.D714G on NM_014902.6) | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59419731; called by muse, mutect2
- DMTN | c.281dup p.P95Tfs*38 | Frame Shift Ins (INS) | VAF 23/154 reads (15%) | catalogued as rs772208110; called by mutect2, varscan2
- DMXL2 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs560768098, COSV51848764; called by muse, mutect2, varscan2
- DMXL2 | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51849610; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs745893364; called by mutect2, varscan2
- DNA2 | c.65C>A p.P22Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.042); catalogued as rs779404104, COSV64429087; called by muse, varscan2
- DNAAF5 | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99859173; called by muse, mutect2
- DNAH10 | c.1756A>G p.S586G (on ENST00000409039; = p.S525G on NM_207437.3) | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV68996209; called by muse, mutect2
- DNAH10 | c.2035T>C p.Y679H (on ENST00000409039; = p.Y618H on NM_207437.3) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV68996211; called by muse, mutect2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH8 | c.6250A>G p.T2084A | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV59459071; called by muse, mutect2
- DNAH8 | c.11381C>T p.A3794V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV59459121; called by muse, mutect2, varscan2
- DNAH9 | c.6665A>G p.K2222R | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV52357922; called by muse, mutect2, varscan2
- DNAI3 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1187129872, COSV54003862; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | catalogued as rs774662919; called by pindel, varscan2
- DNAJB11 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV54003058; called by muse, mutect2
- DNAJB2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV55348117, COSV55349532; called by muse, mutect2, varscan2
- DNAJB5 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs377313197; called by mutect2, varscan2
- DNAJC14 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV57913443; called by muse, mutect2, varscan2
- DNAJC17 | c.296-1G>A p.X99_splice | Splice Site (SNP) | VAF 15/184 reads (8%) | catalogued as COSV55025525; called by muse, mutect2
- DNAJC2 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV50791770; called by muse, mutect2
- DNALI1 | c.587T>C p.F196S (on ENST00000296218; = p.F174S on NM_003462.5) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs547905165, COSV56170424; called by muse, mutect2, varscan2
- DNASE1L2 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57039796; called by muse, mutect2, varscan2
- DNM1 | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57853072; called by muse, mutect2
- DNTTIP1 | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV65459997; called by muse, mutect2
- DNTTIP2 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs757229733, COSV63284275; called by muse, mutect2, varscan2
- DOC2A | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs772945741, COSV58751866; called by muse, mutect2, varscan2
- DOCK10 | c.4987A>G p.T1663A | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV51419522; called by muse, mutect2, varscan2
- DOCK11 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52242184; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.025); catalogued as COSV53917087; called by muse, mutect2, varscan2
- DOCK7 | c.4033C>T p.Q1345* (on ENST00000635253 / NM_001367561.1; = p.Q1314* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 64/229 reads (28%) | catalogued as COSV52011671; called by muse, mutect2, varscan2
- DOCK8 | c.3339dup p.M1114Yfs*4 | Frame Shift Ins (INS) | VAF 18/101 reads (18%) | catalogued as rs748134881; called by mutect2, varscan2
- DPF1 | c.248T>C p.M83T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62793213; called by muse, varscan2
- DPF1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62793224; called by muse, varscan2
- DPY19L4 | c.1339A>G p.K447E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.005); catalogued as rs1476322696, COSV68963215; called by muse, mutect2, varscan2
- DPYSL3 | c.1545del p.A516Qfs*15 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as COSV58330771; called by mutect2, pindel, varscan2
- DRAXIN | c.346G>C p.A116P | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.474); catalogued as COSV53844064; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 22/89 reads (25%) | catalogued as rs750962255; called by mutect2, varscan2
- DTNBP1 | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV59041580; called by muse, mutect2, varscan2
- DTX4 | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57092191; called by muse, mutect2, varscan2
- DUOX2 | c.193T>C p.Y65H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50993950; called by muse, mutect2, varscan2
- DUS2 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV62709030; called by muse, mutect2
- DUSP15 | c.874T>C p.S292P | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1202510100, COSV54066984; called by muse, mutect2, varscan2
- DUSP26 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs114901124; called by muse, mutect2, varscan2
- DUSP9 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV61438149; called by muse, mutect2, varscan2
- DVL3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs143411607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs372512141; called by muse, mutect2, varscan2
- DYSF | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV50460406; called by muse, mutect2, varscan2
- EDC4 | c.2002A>G p.S668G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV59303119; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 31/107 reads (29%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EEF2K | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV53782684, COSV53783770; called by muse, mutect2, varscan2
- EFCAB14 | c.772A>G p.T258A | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as rs1346843561, COSV64239559; called by muse, mutect2
- EFS | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs763985824, COSV53733018; called by muse, mutect2, varscan2
- EGF | c.2055T>C p.G685= | Splice Region (SNP) | VAF 34/231 reads (15%) | catalogued as COSV54480713; called by muse, mutect2, varscan2
- EIF2B3 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV64517856; called by muse, mutect2, varscan2
- EIPR1 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66130951; called by muse, mutect2
- ELAC2 | c.869A>G p.E290G | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV62033178; called by muse, mutect2, varscan2
- ELAVL1 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60967287; called by muse, mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | catalogued as rs751148694; called by mutect2, varscan2
- ELF3 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62838912; called by muse, mutect2
- ELK1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs1349536506, COSV55953430; called by muse, varscan2
- ELK4 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 18/386 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV56985295; called by muse, mutect2
- ELL2 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1561490459, COSV52983540; called by muse, mutect2, varscan2
- ELL2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV52983549; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 61/226 reads (27%) | catalogued as rs766700925; called by mutect2, varscan2
- ELP4 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757353747, COSV63354583; called by muse, mutect2, varscan2
- ELP6 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1392672700, COSV56132555; called by muse, mutect2, varscan2
- EMILIN3 | c.1279A>G p.M427V | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as rs766824674, COSV60037130; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs770453803; called by mutect2, varscan2
- ENDOD1 | c.1016T>C p.F339S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1453729575, COSV53590027; called by muse, mutect2, varscan2
- ENOX1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 74/227 reads (33%) | catalogued as COSV54905500; called by muse, mutect2, varscan2
- ENPEP | c.2736dup p.A913Cfs*13 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | catalogued as rs768719919; called by mutect2, pindel, varscan2
- ENPP2 | c.1455+2T>C p.X485_splice (on ENST00000075322 / NM_001040092.3; = p.X537_splice on NM_006209.5) | Splice Site (SNP) | VAF 19/453 reads (4%) | catalogued as rs1298927363, COSV50020523; called by muse, mutect2
- ENPP4 | c.628del p.I210* | Frame Shift Del (DEL) | VAF 43/152 reads (28%) | catalogued as rs756006851; called by mutect2, pindel, varscan2
- ENY2 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV53453963, COSV53458187; called by muse, mutect2
- EP300 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 79/228 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV54336553; called by muse, mutect2, varscan2
- EPAS1 | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV55387805; called by muse, varscan2
- EPB41 | c.868C>T p.P290S (on ENST00000343067 / NM_001166005.2; = p.P81S on NM_004437.4) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100548111, COSV58049788; called by muse, varscan2
- EPB41L4A | c.1577del p.N526Tfs*46 | Frame Shift Del (DEL) | VAF 30/128 reads (23%) | catalogued as rs755555590; called by mutect2, varscan2
- EPB41L4B | c.541T>A p.F181I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV65797586; called by muse, mutect2, varscan2
- EPB42 | c.940C>T p.Q314* (on ENST00000441366 / NM_001114134.2; = p.Q344* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 175/508 reads (34%) | catalogued as COSV55750342; called by muse, mutect2, varscan2
- EPHA2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756877965, COSV64453725; called by muse, mutect2, varscan2
- EPHA6 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1345769003, COSV67579027, COSV67582022; called by muse, mutect2, varscan2
- EPYC | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 44/131 reads (34%) | catalogued as COSV53800521; called by muse, mutect2, varscan2
- ERCC4 | c.1085A>G p.E362G | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV61312682; called by muse, mutect2
- ERCC6L2 | c.1938A>G p.I646M | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1203454043, COSV56632009; called by muse, mutect2
- ERCC8 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54016532; called by muse, mutect2, varscan2
- ERICH1 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.281); catalogued as COSV50638997; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs753821453; called by mutect2, varscan2
- ERP27 | c.737A>G p.Q246R | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV56763869; called by muse, mutect2, varscan2
- ESF1 | c.2210del p.K737Rfs*7 | Frame Shift Del (DEL) | VAF 52/162 reads (32%) | catalogued as COSV52521296, COSV52523812; called by mutect2, varscan2
- ESF1 | c.1733A>T p.Q578L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV52522287; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 24/106 reads (23%) | catalogued as rs775950025; called by mutect2, varscan2
- ETFDH | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763912783, CM166215, COSV56986953; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ETS1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV60094566; called by muse, mutect2, varscan2
- ETV4 | c.399dup p.R134Qfs*49 | Frame Shift Ins (INS) | VAF 20/69 reads (29%) | catalogued as rs745944421; called by mutect2, varscan2
- EVC | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs771068713, COSV53834370; called by muse, mutect2
- EVL | c.1031C>T p.P344L (on ENST00000402714 / NM_001330221.2; = p.P346L on NM_016337.3) | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs773230379, COSV67374574; called by muse, mutect2, varscan2
- EXO1 | c.543+2T>C p.X181_splice | Splice Site (SNP) | VAF 35/93 reads (38%) | catalogued as COSV62218220; called by muse, mutect2, varscan2
- EXO5 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV56415965; called by muse, mutect2
- EXOC5 | c.1744T>A p.Y582N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV61771351; called by muse, mutect2, varscan2
- EXOSC8 | c.165T>A p.N55K | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV53506130, COSV53507354; called by muse, mutect2, varscan2
- F11 | c.57A>G p.E19= | Splice Region (SNP) | VAF 44/151 reads (29%) | catalogued as COSV53007745; called by muse, mutect2, varscan2
- F12 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 72/231 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV53691884; called by muse, mutect2, varscan2
- F5 | c.4298T>C p.L1433P | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV63125536; called by muse, mutect2, varscan2
- F7 | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372307787; called by muse, mutect2, varscan2
- F7 | c.997C>A p.L333M | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1462083049, COSV60646679; called by muse, mutect2, varscan2
- FA2H | c.635A>T p.K212M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV54726849; called by mutect2, varscan2
- FAAH2 | c.412+2T>C p.X138_splice | Splice Site (SNP) | VAF 23/69 reads (33%) | catalogued as COSV66507728; called by muse, mutect2, varscan2
- FAF1 | c.29T>G p.I10S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV52955217; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM118A | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV53417223; called by muse, mutect2, varscan2
- FAM135B | c.3676T>C p.S1226P | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52735310; called by muse, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM163B | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100618870; called by muse, mutect2, varscan2
- FAM178B | c.1877T>C p.M626T (on ENST00000490605 / NM_001122646.3; = p.M66T on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.114); catalogued as COSV59971267; called by muse, mutect2, varscan2
- FAM184A | c.2465G>A p.R822H | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs370372665; called by muse, mutect2, varscan2
- FAM193A | c.2017del p.L673Sfs*142 | Frame Shift Del (DEL) | VAF 65/264 reads (25%) | catalogued as COSV61191975; called by mutect2, pindel, varscan2
- FAM193B | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as rs769082254, COSV61558125; called by muse, mutect2, varscan2
- FAM207A | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.552); catalogued as rs367559441; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM222A | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV62723587; called by muse, mutect2, varscan2
- FAM43A | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61673239; called by muse, mutect2, varscan2
- FAM50B | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757035966, COSV66654902; called by muse, mutect2, varscan2
- FAM83H | c.3170T>C p.V1057A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62028935; called by muse, varscan2
- FAM83H | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1554623554, COSV66353860, COSV66354082; called by muse, mutect2, varscan2
- FAM98A | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99479002; called by muse, mutect2, varscan2
- FAM98B | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as COSV59843084; called by muse, mutect2
- FAN1 | c.1144_1146del p.V382del | In Frame Del (DEL) | VAF 52/214 reads (24%) | catalogued as rs1338332863; called by pindel, varscan2
- FANCE | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs181761362, COSV57690335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs143812680; called by muse, mutect2, varscan2
- FAT3 | c.2449C>A p.L817M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53133456; called by muse, mutect2, varscan2
- FAT3 | c.6950A>G p.E2317G | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53133478; called by mutect2, varscan2
- FAT4 | c.8971T>C p.F2991L | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as rs1345394683, COSV58693216; called by muse, mutect2
- FBF1 | c.2645G>A p.R882H (on ENST00000586717; = p.R896H on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1479510565, COSV59865734; called by muse, mutect2, varscan2
- FBH1 | c.2132T>C p.V711A (on ENST00000362091 / NM_178150.3; = p.V762A on NM_032807.4) | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62983182; called by muse, mutect2, varscan2
- FBL | c.666A>C p.K222N | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV55683147; called by muse, mutect2, varscan2
- FBN2 | c.2711A>T p.D904V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV52524277; called by muse, mutect2, varscan2
- FBN3 | c.5187del p.A1730Pfs*9 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as COSV54468680; called by mutect2, pindel, varscan2
- FBN3 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV54464839; called by muse, mutect2, varscan2
- FBXO21 | c.1256A>G p.Y419C | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.921); catalogued as COSV57973665; called by muse, mutect2, varscan2
- FBXO22 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57617916; called by muse, mutect2
- FBXO32 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV54891474; called by muse, mutect2
- FBXO47 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV65242118; called by muse, mutect2, varscan2
- FBXW11 | c.139T>C p.C47R | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); catalogued as COSV51610835; called by muse, mutect2, varscan2
- FCGR2A | c.847A>G p.T283A (on ENST00000271450 / NM_001136219.3; = p.T282A on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54839400; called by muse, mutect2, varscan2
- FCHSD1 | c.1978C>A p.L660M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.467); catalogued as COSV51837807; called by muse, mutect2, varscan2
- FCRL2 | c.739A>G p.S247G | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV63834079; called by muse, mutect2, varscan2
- FER1L5 | c.5864G>A p.R1955Q (on ENST00000623019; = p.R1919Q on NM_001293083.2) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1371809293, COSV53840621; called by muse, mutect2, varscan2
- FERMT2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV58407917; called by muse, varscan2
- FGF14 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs535952842, COSV65937296; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGF17 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs142215324; called by muse, mutect2, varscan2
- FHDC1 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52601023; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIG4 | c.2693A>G p.Y898C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57788791; called by muse, mutect2, varscan2
- FIGNL1 | c.926del p.K309Sfs*16 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as rs1216734611; called by mutect2, pindel, varscan2
- FILIP1L | c.2732T>C p.V911A (on ENST00000354552 / NM_182909.3; = p.V671A on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58771375; called by muse, mutect2, varscan2
- FKBP3 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV53532919; called by muse, varscan2
- FLG | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 138/428 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64242847, COSV64243659; called by mutect2, varscan2
- FLNB | c.40T>C p.W14R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55884392; called by muse, mutect2
- FLNC | c.3911T>C p.V1304A | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs377011299; called by muse, mutect2, varscan2
- FLYWCH1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV99558503; called by muse, mutect2, varscan2
- FN1 | c.2626T>C p.Y876H | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60556625; called by muse, mutect2
- FN1 | c.2197G>A p.A733T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as COSV60556641; called by muse, mutect2, varscan2
- FNDC3B | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61044944; called by muse, mutect2, varscan2
- FNDC3B | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV61044979; called by muse, varscan2
- FOCAD | c.2625+2T>C p.X875_splice | Splice Site (SNP) | VAF 48/146 reads (33%) | catalogued as rs145752860; called by muse, mutect2, varscan2
- FOSB | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1409932989, COSV62278481; called by muse, mutect2, varscan2
- FOXG1 | c.712T>A p.C238S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57397792; called by muse, mutect2, varscan2
- FOXK1 | c.1729A>G p.T577A | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as COSV61066903; called by muse, mutect2, varscan2
- FOXP1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as rs1358353721, COSV59520546; called by muse, varscan2
- FPGT | c.1760A>G p.E587G | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV63842366; called by muse, mutect2, varscan2
- FRAS1 | c.8606A>G p.Y2869C | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); catalogued as COSV53623279; called by muse, mutect2, varscan2
- FREM2 | c.3608G>A p.G1203D | Missense Mutation (SNP) | VAF 55/493 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV54842387; called by muse, mutect2, varscan2
- FREM2 | c.6712A>G p.T2238A | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1164532909, COSV54842401; called by muse, mutect2, varscan2
- FRMD6 | c.688G>A p.A230T (on ENST00000344768 / NM_001267046.2; = p.A222T on NM_152330.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs374236968; called by muse, mutect2, varscan2
- FRMPD2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59719656; called by muse, mutect2, varscan2
- FRMPD3 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360596559, COSV52188168; called by muse, mutect2, varscan2
- FRYL | c.8867C>T p.T2956M | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as rs763784117, COSV51951786; called by muse, mutect2, varscan2
- FSHR | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58627191; called by muse, mutect2, varscan2
- FURIN | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs138927071, COSV51577780; called by muse, mutect2, varscan2
- FUZ | c.1169T>G p.L390R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226811597, COSV58241812; called by muse, varscan2
- GABBR2 | c.775A>G p.M259V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as rs771593744, COSV52309872; called by muse, mutect2, varscan2
- GABPB2 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1476591871, COSV64461100; called by muse, mutect2, varscan2
- GABRR1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65619795; called by muse, mutect2, varscan2
- GAD2 | c.1460del p.N487Tfs*37 | Frame Shift Del (DEL) | VAF 46/195 reads (24%) | catalogued as rs1564673119; called by mutect2, pindel, varscan2
- GAL3ST4 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as COSV57586906; called by muse, mutect2
- GAPDHS | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.076); catalogued as COSV55883058; called by muse, mutect2
- GATA1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs201489369, COSV64962528, COSV64962619; called by muse, mutect2
- GBX2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs752822897, COSV60445508; called by muse, mutect2, varscan2
- GDA | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV52993755; called by muse, mutect2, varscan2
- GDF2 | c.1244A>G p.K415R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1555209096; called by muse, mutect2, varscan2
- GEMIN5 | c.2906C>G p.A969G | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV53561935; called by muse, mutect2, varscan2
- GFM2 | c.1693C>T p.R565* | Nonsense Mutation (SNP) | VAF 32/106 reads (30%) | catalogued as rs920594032, COSV57191699; called by muse, mutect2, varscan2
- GFOD1 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.185); catalogued as COSV64954918; called by muse, mutect2
- GFRAL | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV61232438; called by muse, mutect2, varscan2
- GGT1 | c.1366A>T p.T456S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.052); catalogued as COSV50641624; called by muse, mutect2, varscan2
- GJA1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as CM055952; called by muse, mutect2, varscan2
- GJA4 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV60725635; called by muse, mutect2
- GJB6 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1566538446, CM078517, COSV53832867; called by muse, mutect2, varscan2
- GK | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as COSV66734470; called by muse, mutect2, varscan2
- GLI3 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as rs1296035859, COSV67890481; called by muse, mutect2, varscan2
- GLT6D1 | c.679T>C p.Y227H | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65627972; called by muse, mutect2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs749150409; called by mutect2, varscan2
- GLYR1 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); catalogued as COSV52169536; called by muse, mutect2
- GMEB1 | c.186C>A p.N62K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV53795153; called by muse, varscan2
- GNAI2 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56495154; called by muse, mutect2, varscan2
- GNAZ | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV50739445; called by muse, mutect2, varscan2
- GNPAT | c.1661A>G p.K554R | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV64153724; called by muse, mutect2, varscan2
- GNPDA2 | c.282del p.F94Lfs*6 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs1489322870; called by mutect2, pindel, varscan2
- GNPTAB | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); catalogued as COSV100171608; called by muse, mutect2, varscan2
- GOLGA3 | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199808370, COSV52635526; called by muse, mutect2, varscan2
- GOLGA3 | c.1912A>G p.I638V | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs764392819, COSV52635557; called by muse, mutect2, varscan2
- GOLGB1 | c.6445C>T p.R2149C | Missense Mutation (SNP) | VAF 115/391 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs114710035; called by muse, mutect2, varscan2
- GPATCH2L | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | catalogued as COSV55049341; called by muse, mutect2, varscan2
- GPR137 | c.1124C>A p.P375H | Missense Mutation (SNP) | VAF 75/242 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.224); catalogued as COSV57402808; called by muse, mutect2, varscan2
- GPR137C | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV55985490; called by muse, mutect2, varscan2
- GPR151 | c.1025A>G p.N342S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.039); catalogued as COSV57038753; called by muse, mutect2, varscan2
- GPR162 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1276081042, COSV50589413; called by muse, mutect2, varscan2
- GPR173 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs1427100063, COSV60236715; called by muse, mutect2, varscan2
- GPR183 | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63119041; called by muse, mutect2, varscan2
- GPR22 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as COSV51755806; called by muse, mutect2, varscan2
- GPR3 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as COSV64995008; called by muse, mutect2
- GPR55 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1234989198, COSV67407671; called by muse, varscan2
- GPR55 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.179); catalogued as COSV67408060; called by muse, varscan2
- GPT2 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV60839259; called by muse, varscan2
- GRB14 | c.1023+2T>C p.X341_splice | Splice Site (SNP) | VAF 22/73 reads (30%) | catalogued as COSV55739585; called by muse, mutect2, varscan2
- GRHL3 | c.844G>A p.V282M (on ENST00000350501 / NM_198174.3; = p.V287M on NM_021180.3) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV52568192; called by muse, mutect2, varscan2
- GRIK4 | c.1809del p.F604Sfs*27 | Frame Shift Del (DEL) | VAF 20/80 reads (25%) | catalogued as COSV70801839; called by pindel, varscan2
- GRIN2A | c.4021del p.S1341Afs*56 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | catalogued as COSV58051797; called by mutect2, pindel, varscan2
- GRM1 | c.2839del p.S947Qfs*11 | Frame Shift Del (DEL) | VAF 61/220 reads (28%) | catalogued as rs34444335; called by mutect2, pindel, varscan2
- GRN | c.433G>T p.G145C | Missense Mutation (SNP) | VAF 78/295 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50007736; called by muse, mutect2, varscan2
- GSE1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1201882241, COSV53672084; called by muse, mutect2
- GSE1 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53673319; called by muse, mutect2, varscan2
- GSE1 | c.3136G>A p.V1046M | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.683); catalogued as rs766062436, COSV53673327; called by muse, mutect2, varscan2
- GSK3A | c.1193G>A p.C398Y | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55899854; called by muse, mutect2
- GSX1 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV57233252; called by muse, mutect2, varscan2
- GTF2IRD1 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV56088184; called by muse, mutect2, varscan2
- GTF3C1 | c.6074A>G p.Y2025C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62242403; called by muse, mutect2
- GTF3C1 | c.5566A>G p.S1856G | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62242408; called by muse, mutect2
- GTF3C1 | c.3541G>A p.A1181T | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV62242413; called by muse, mutect2, varscan2
- GTPBP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 80/260 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53285985; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | catalogued as COSV54945907; called by mutect2, varscan2
- GYG2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223369, COSV58550649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H1-4 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56802015; called by muse, mutect2
- H1-5 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58900529; called by muse, mutect2, varscan2
- H2AC20 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1553759892, COSV58612420; called by muse, mutect2, varscan2
- H2AP | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1242604480, COSV61910916; called by muse, mutect2, varscan2
- H2BC5 | c.356T>A p.V119D | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV56802030; called by muse, mutect2, varscan2
- H3C6 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV64519400, COSV64519670; called by muse, mutect2, varscan2
- HAGH | c.638del p.P213Rfs*61 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs751524326; called by mutect2, pindel
- HAND1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1353975436, COSV50562798; called by muse, mutect2, varscan2
- HAS2 | c.1363A>T p.I455F | Missense Mutation (SNP) | VAF 16/493 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV58265099; called by muse, mutect2
- HBM | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.132); catalogued as COSV61575387; called by muse, mutect2
- HCRTR1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 52/229 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs772394538, COSV65485830; called by muse, mutect2, varscan2
- HDAC4 | c.3017A>G p.Q1006R | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1261150143, COSV61860398; called by muse, mutect2
- HDAC6 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs147989097, COSV61929547; called by muse, mutect2, varscan2
- HDC | c.1129C>G p.H377D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51073140; called by muse, mutect2, varscan2
- HDLBP | c.1934C>T p.S645F | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV60497840; called by muse, mutect2, varscan2
- HEATR1 | c.3622A>G p.T1208A | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV63981839; called by muse, mutect2, varscan2
- HECTD3 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750399285, COSV64670421; called by muse, mutect2, varscan2
- HECTD4 | c.13100dup p.D4368Rfs*44 | Frame Shift Ins (INS) | VAF 32/149 reads (21%) | catalogued as rs746492036; called by mutect2, varscan2
- HECTD4 | c.3836C>A p.P1279H | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61180190; called by muse, mutect2, varscan2
- HECW1 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67833306; called by muse, mutect2, varscan2
- HELB | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); catalogued as COSV56074470; called by muse, mutect2
- HEPH | c.1442G>T p.S481I (on ENST00000343002; = p.S214I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100294401, COSV57966447; called by muse, mutect2, varscan2
- HERC2 | c.13226T>C p.V4409A | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV55320330; called by muse, mutect2, varscan2
- HERC2 | c.11999T>C p.V4000A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55331557; called by muse, mutect2, varscan2
- HERC2 | c.10398G>A p.W3466* | Nonsense Mutation (SNP) | VAF 57/236 reads (24%) | catalogued as COSV55331583; called by muse, mutect2, varscan2
- HERC2 | c.7480+2T>C p.X2494_splice | Splice Site (SNP) | VAF 7/71 reads (10%) | catalogued as COSV55331607; called by muse, mutect2
- HERC2 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55331629; called by muse, mutect2, varscan2
- HERC5 | c.418del p.I140* | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs770854785; called by mutect2, varscan2
- HEXB | c.1559G>C p.R520T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs758359266, COSV54668766; called by muse, mutect2, varscan2
- HGH1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1332425622; called by muse, mutect2, varscan2
- HIC2 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753116016, COSV68042072; called by muse, mutect2, varscan2
- HINFP | c.955T>C p.C319R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63432245; called by muse, mutect2
2,114 further variants in this file (1,382 protein-altering or splice-affecting, 659 silent, 73 other) are not listed here.
